Somatic mutation profile of tumor specimen MMRF_2160_1_BM_CD138pos (aliquot MMRF_2160_1_BM_CD138pos_T1_KHS5U_L08851) from MMRF case MMRF_2160, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.3 years (24,964 days).
Specimen MMRF_2160_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45752f26-640a-4368-9339-b822ccbac143.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2160_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2160_1_PB_Whole_C3_KHS5U_L08786; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/723b0ebf-6341-4ac2-8b65-8d3f851f073f

The open-access MAF lists 110 somatic variants for this specimen: 44 protein-altering or splice-affecting, 4 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 35, Intron 10, 5'UTR 7, Silent 4, 3'Flank 4, RNA 4, Splice Site 2, Nonsense Mutation 2, 5'Flank 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC2H1 | c.1355_1358del p.I452Kfs*5 | Frame Shift Del (DEL) | VAF 23/79 reads (29%) | catalogued as rs1223907858; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 24/61 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARAP3 | c.3692G>A p.R1231Q | Missense Mutation (SNP) | VAF 85/285 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs140628013; called by muse, mutect2, varscan2
- ASIC1 | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV57316964; called by muse, mutect2, varscan2
- C5 | c.2503C>T p.R835* | Nonsense Mutation (SNP) | VAF 74/262 reads (28%) | catalogued as COSV56325970; called by muse, mutect2, varscan2
- CHRD | c.2197-2A>G p.X733_splice | Splice Site (SNP) | VAF 35/161 reads (22%) | catalogued as COSV52610720; called by muse, mutect2, varscan2
- CNGA1 | c.1622G>A p.G541D | Missense Mutation (SNP) | VAF 102/222 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373120472; called by muse, mutect2, varscan2
- COL12A1 | c.1322T>C p.I441T | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.341); catalogued as rs1223531902; called by muse, mutect2, varscan2
- DISP3 | c.3880G>A p.V1294I | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.686); catalogued as rs775248733, COSV53823292; called by muse, mutect2, varscan2
- EPB41L4B | c.2140G>A p.V714M | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as rs201636849, COSV63124046; called by muse, mutect2, varscan2
- HDAC9 | c.2840G>A p.R947H | Missense Mutation (SNP) | VAF 82/172 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs916051816, COSV101286501, COSV67768594, COSV67784848; called by muse, mutect2, varscan2
- IGHD7-27 | c.1C>G p.L1V | Missense Mutation (SNP) | VAF 24/24 reads (100%) | PolyPhen probably damaging (0.998); catalogued as rs561109248; called by muse, varscan2
- IGLL5 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.08); catalogued as rs538723125, COSV73251010, COSV73251135, COSV73251305; called by muse, mutect2, varscan2
- MAP1A | c.7415G>C p.R2472P | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.68); catalogued as rs148897210, COSV55812231; called by muse, mutect2, varscan2
- OR5M3 | c.317T>C p.V106A | Missense Mutation (SNP) | VAF 189/424 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs1336921542; called by muse, mutect2, varscan2
- PCDHGA9 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs1454199669; called by muse, mutect2, varscan2
- PLLP | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.089); catalogued as rs756501535; called by muse, mutect2, varscan2
- TET1 | c.5596G>A p.A1866T | Missense Mutation (SNP) | VAF 102/222 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs767435262; called by muse, mutect2, varscan2
- CLTCL1 | c.3049G>A p.V1017I | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- DNAH10 | c.6409G>A p.A2137T (on ENST00000409039; = p.A2076T on NM_207437.3) | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- FSCN1 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- FZD10 | c.1412A>C p.Y471S | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- GAREM2 | c.1984C>T p.P662S | Missense Mutation (SNP) | VAF 62/123 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- GFPT2 | c.159C>G p.H53Q | Missense Mutation (SNP) | VAF 17/388 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- GPA33 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- HEATR5A | c.5117A>C p.K1706T | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- HNRNPM | c.113+1G>A p.X38_splice | Splice Site (SNP) | VAF 36/142 reads (25%) | called by muse, mutect2, varscan2
- IGKV1D-13 | c.293G>A p.S98N | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.246); called by muse, varscan2
- INTS12 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, varscan2
- METTL22 | c.591C>G p.I197M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MXRA5 | c.3089G>C p.G1030A | Missense Mutation (SNP) | VAF 48/55 reads (87%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCBP1 | c.1387C>A p.Q463K | Missense Mutation (SNP) | VAF 73/233 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- NWD1 | c.2742G>T p.R914S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- PDE3A | c.1626T>G p.I542M | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POC1B | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- POLR2A | c.2446G>A p.G816R | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRPF31 | c.337T>A p.F113I | Missense Mutation (SNP) | VAF 16/321 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2
- SI | c.908A>C p.E303A | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- STAB2 | c.6676A>G p.T2226A | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- STON2 | c.1905A>C p.E635D (on ENST00000649389 / NM_001366849.2; = p.E578D on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- TM2D3 | c.540G>A p.W180* (on ENST00000333202 / NM_078474.3; = p.W154* on NM_025141.3) | Nonsense Mutation (SNP) | VAF 44/146 reads (30%) | called by muse, mutect2, varscan2
- TRPC7 | c.269A>G p.H90R | Missense Mutation (SNP) | VAF 64/343 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- ZC3H6 | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 9/242 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZFP36L2 | c.1360T>C p.S454P | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- CELF6 | c.744G>A p.T248= | Silent (SNP) | VAF 35/51 reads (69%) | called by muse, mutect2, varscan2
- COL4A4 | c.1479C>T p.A493= | Silent (SNP) | VAF 55/105 reads (52%) | called by muse, mutect2, varscan2
- H4C12 | c.213G>A p.V71= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs764527111; called by muse, mutect2, varscan2
- ZFP14 | c.1437T>G p.P479= | Silent (SNP) | VAF 32/51 reads (63%) | called by muse, mutect2, varscan2
- AC008060.1 | n.950T>G | RNA (SNP) | VAF 48/103 reads (47%) | called by muse, mutect2, varscan2
- ACTN4 | c.2418+203T>G | Intron (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- AK4 | c.*2879_*2882del | 3'UTR (DEL) | VAF 21/39 reads (54%) | catalogued as rs992194835; called by mutect2, pindel, varscan2
- AL513174.1 | n.111C>G | RNA (SNP) | VAF 27/70 reads (39%) | called by muse, varscan2
- ANTXR2 | c.*705C>T | 3'UTR (SNP) | VAF 31/74 reads (42%) | catalogued as rs754910280; called by muse, mutect2, varscan2
- APLN | c.*114G>A | 3'UTR (SNP) | VAF 59/65 reads (91%) | catalogued as rs1191225463; called by muse, varscan2
- BCOR | c.*176_*182del | 3'UTR (DEL) | VAF 11/12 reads (92%) | called by mutect2, varscan2
- BORCS7 | c.*1245A>T | 3'UTR (SNP) | VAF 34/66 reads (52%) | called by muse, mutect2, varscan2
- BRINP1 | c.922+245C>T | Intron (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- C11orf53 | c.*220G>A | 3'UTR (SNP) | VAF 66/168 reads (39%) | called by muse, mutect2, varscan2
- CAMK2B | c.1340-184C>T | Intron (SNP) | VAF 42/83 reads (51%) | called by muse, mutect2, varscan2
- CHID1 | c.*330G>A | 3'UTR (SNP) | VAF 56/212 reads (26%) | called by muse, mutect2, varscan2
- CLVS2 | c.-189del | 5'UTR (DEL) | VAF 28/65 reads (43%) | catalogued as rs949735203; called by mutect2, pindel, varscan2
- COMMD2 | c.-5T>G | 5'UTR (SNP) | VAF 101/311 reads (32%) | called by muse, mutect2, varscan2
- CPPED1 | c.*483A>C | 3'UTR (SNP) | VAF 27/57 reads (47%) | called by muse, mutect2, varscan2
- CTNS | c.*935C>G | 3'UTR (SNP) | VAF 78/154 reads (51%) | called by muse, mutect2, varscan2
- CYP2F1 | c.1294+136C>G | Intron (SNP) | VAF 144/644 reads (22%) | called by muse, mutect2, varscan2
- DPP8 | c.-247T>G | 5'UTR (SNP) | VAF 40/139 reads (29%) | called by muse, mutect2, varscan2
- DRC3 | c.-17-42A>G | Intron (SNP) | VAF 110/188 reads (59%) | called by muse, mutect2, varscan2
- GRIK3 | c.*6100A>G | 3'UTR (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2, varscan2
- GZF1 | c.*2303G>A | 3'UTR (SNP) | VAF 38/95 reads (40%) | called by muse, mutect2, varscan2
- HEATR6 | c.*21G>T | 3'UTR (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- HEY1 | c.89+130G>A | Intron (SNP) | VAF 47/116 reads (41%) | catalogued as rs1311762826; called by muse, mutect2, varscan2
- KANK4 | c.*428A>T | 3'UTR (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- KCNJ11 | c.*134G>C | 3'UTR (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
- KCNMB4 | c.*3503C>T | 3'UTR (SNP) | VAF 103/183 reads (56%) | called by muse, mutect2, varscan2
- KDELR2 | c.*1106T>C | 3'UTR (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- KIF21A | chr12:39443242 G>A | 5'Flank (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- KRTAP9-4 | c.*370T>C | 3'UTR (SNP) | VAF 93/202 reads (46%) | called by muse, varscan2
- LAPTM4B | c.-217_-216del | 5'UTR (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel
- LINC02228 | n.235T>G | RNA (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- LPP | c.1240+2298T>C | Intron (SNP) | VAF 29/110 reads (26%) | called by muse, mutect2, varscan2
- MDGA2 | c.*149G>A | 3'UTR (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- MEIS2 | c.-339T>C | 5'UTR (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- NAGK | c.*1163A>G | 3'UTR (SNP) | VAF 7/15 reads (47%) | catalogued as rs1387783823; called by muse, mutect2, varscan2
- NAP1L4 | c.*539A>G | 3'UTR (SNP) | VAF 51/187 reads (27%) | catalogued as rs369092636; called by muse, mutect2, varscan2
- NPY2R | c.*1597A>G | 3'UTR (SNP) | VAF 28/54 reads (52%) | called by muse, mutect2, varscan2
- NTSR1 | c.*1383T>A | 3'UTR (SNP) | VAF 15/173 reads (9%) | called by muse, mutect2
- OGFR | c.241-158C>T | Intron (SNP) | VAF 23/102 reads (23%) | called by muse, mutect2, varscan2
- OR11K2P | n.675G>A | RNA (SNP) | VAF 52/184 reads (28%) | called by muse, mutect2, varscan2
- PANX1 | c.*291A>T | 3'UTR (SNP) | VAF 41/191 reads (21%) | called by muse, mutect2, varscan2
- PDZD8 | c.*122dup | 3'UTR (INS) | VAF 26/46 reads (57%) | called by mutect2, pindel, varscan2
- PTGR2 | chr14:73886806 del CCAAACTTCCTGTCCCGCGCTCGAGCTGCTT | 3'Flank (DEL) | VAF 50/148 reads (34%) | called by mutect2, pindel
- RASAL2 | c.*9G>A | 3'UTR (SNP) | VAF 135/280 reads (48%) | called by muse, mutect2, varscan2
- RIT2 | chr18:43115868 T>C | 5'Flank (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- SCNN1D | c.-953T>G | 5'UTR (SNP) | VAF 32/66 reads (48%) | called by muse, mutect2, varscan2
- SEMA3D | c.*16A>G | 3'UTR (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- SEPTIN6 | chrX:119617022 del AAC | 3'Flank (DEL) | VAF 18/21 reads (86%) | called by mutect2, pindel, varscan2
- SLC1A2 | c.-122G>A | 5'UTR (SNP) | VAF 34/148 reads (23%) | catalogued as rs869190967; called by muse, mutect2
- SLC26A7 | c.*1478A>T | 3'UTR (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- SLCO1C1 | c.*29T>G | 3'UTR (SNP) | VAF 117/270 reads (43%) | called by muse, mutect2, varscan2
- SPANXD | c.*4G>T | 3'UTR (SNP) | VAF 48/55 reads (87%) | called by muse, mutect2, varscan2
- SPECC1 | chr17:20315360 C>T | 3'Flank (SNP) | VAF 5/64 reads (8%) | catalogued as rs1440139343; called by muse, mutect2
- SSR1 | c.*4820C>G | 3'UTR (SNP) | VAF 38/89 reads (43%) | called by muse, mutect2, varscan2
- STMN2 | c.*1235T>G | 3'UTR (SNP) | VAF 42/78 reads (54%) | called by muse, mutect2, varscan2
- SYT4 | c.*2289G>A | 3'UTR (SNP) | VAF 24/38 reads (63%) | called by muse, mutect2, varscan2
- TECRL | chr4:64276947 G>C | 3'Flank (SNP) | VAF 42/117 reads (36%) | called by muse, mutect2
- TEPSIN | c.816-33del | Intron (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- TNFRSF10B | c.*464G>A | 3'UTR (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- TOLLIP | c.*1947C>T | 3'UTR (SNP) | VAF 45/97 reads (46%) | called by muse, mutect2, varscan2
- UGT2A3 | c.*1293G>A | 3'UTR (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2
- UNG | c.133-210T>C | Intron (SNP) | VAF 43/87 reads (49%) | called by muse, mutect2, varscan2
